Somatic mutation profile of tumor specimen 0DKII9 from CCDI case PBBXXP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 16.5 years (6,026 days).
Specimen 0DKII9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90b01e05-7a66-462a-a8dd-2f241f589b6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKIHS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0211aa7-a188-42f1-ad81-a0dca231fbdd

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND2B | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs767544037; called by muse, mutect2, varscan2
- ATRX | c.5786A>C p.K1929T | Missense Mutation (SNP) | VAF 333/841 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MUC16 | c.38495C>A p.T12832K | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.322); called by muse, varscan2
- TMPRSS3 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 192/494 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- LIPH | c.873C>T p.S291= | Silent (SNP) | VAF 28/722 reads (4%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
